TCGA case TCGA-06-0210 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de7b7cac-f094-4d59-8651-e991e34ea093

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 225 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 72.8 years (26,600 days); Year of diagnosis: 1997; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 123 days; Days to treatment end: 148 days; Treatment dose: 3,270 cGy; Number of fractions: 20; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 73.0 years (26,667 days); Days to diagnosis: 67 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 67 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 67 (post initial treatment): Progression or recurrence: Yes; Days to progression: 67 days.
- Days to follow up: 151 days; Disease response: With Tumor.
- Days to follow up: 225 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0210-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-06-0210-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
- Sample TCGA-06-0210-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0210-01B-01-TS1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 90; Percent stromal cells: 0.
  Slide TCGA-06-0210-01B-01-BS1: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 85; Percent stromal cells: 0.
- Sample TCGA-06-0210-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0210-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-06-0210-02A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-06-0210-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Radiation treatment: Therapy regimen other: Patient stopped radiation and enrolled in hospice.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 225 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 225 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 67 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0210-01B-01D-0236-01): tumor purity 0.45, ploidy 1.96, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0210-02A-01D-2002-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 1.
